CPTAC case C3L-03963 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6145ec3f-90c8-4fc9-8f49-9f2d699da65a

Demographics
Sex at birth: male; Race: white; Year of birth: 1945; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 73.2 years (26,748 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,398 days (3.8 years); Progression or recurrence: no; Days to last follow up: 1,398 days (3.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 6 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 8; Margin status: Uninvolved.

Follow-up (5 entries)
- Days to follow up: 484 days (1.3 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 778 days (2.1 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 993 days (2.7 years); Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 993 days (2.7 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,398 days (3.8 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Weight: 85 kg; Height: 170 cm; BMI: 29.41; FEV1 before bronchodilator (% of reference): 77.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 60; Cigarettes per day: 20; Tobacco smoking onset year: 1958; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 64; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03963-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 333 mg; Time between clamping and freezing: 33 minutes; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03963-24: Section location: Left Upper Lobe; Percent tumor nuclei: 65; Percent necrosis: 15.
- Sample C3L-03963-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 135 mg; Time between clamping and freezing: 35 minutes; Time between excision and freezing: 20 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-03963-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -7 days; Method of sample procurement: Blood Draw.
